Somatic mutation profile of tumor specimen TARGET-30-PASYIP-01A (aliquot TARGET-30-PASYIP-01A-01D) from TARGET case TARGET-30-PASYIP, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.3 years (829 days).
Specimen TARGET-30-PASYIP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77eb33b2-e76a-4a34-9b10-dfee8e7d546b.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASYIP-10A (Blood Derived Normal), aliquot TARGET-30-PASYIP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cad9533b-00c6-4332-b3cb-409412abe888

The open-access MAF lists 5 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 3, Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>T p.R213L | Missense Mutation (SNP) | VAF 53/73 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SPECC1 | c.651C>A p.V217= | Silent (SNP) | VAF 24/134 reads (18%) | called by muse, varscan2
- GAREM1 | c.*2735G>T | 3'UTR (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- PLXNB1 | c.*454G>T | 3'UTR (SNP) | VAF 26/51 reads (51%) | catalogued as COSV56493425; called by muse, mutect2, varscan2
- TIAM1 | c.*1484C>A | 3'UTR (SNP) | VAF 51/116 reads (44%) | catalogued as COSV54552474; called by muse, mutect2, varscan2
